TCGA case TCGA-30-1714 — Ovarian Serous Cystadenocarcinoma (TCGA-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary; Tissue source site: Harvard. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/09820a33-80b1-42d0-8366-a0ddaf94b122

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 68 years; Vital status: Dead; Days to death: 1,158 days (3.2 years); Population group: Ashkenazi Jew.

Diagnoses (2)
1. Serous cystadenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8441/3; ICD-10 code: C56.9; Tissue or organ of origin: Ovary; Site of resection or biopsy: Ovary; Laterality: Bilateral; Classification of tumor: primary; Age at diagnosis: 68.5 years (25,032 days); Year of diagnosis: 2001; Method of diagnosis: Surgical Resection; FIGO stage: Stage IV; Tumor grade: G3; Prior treatment: No.
   Pathology details: Lymphatic invasion present: Yes; Residual tumor measurement: 1-10 mm; Vascular invasion present: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Treatment intent type: Adjuvant; Days to treatment start: 15 days; Days to treatment end: 123 days; Number of cycles: 6; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Days to treatment start: 15 days; Days to treatment end: 123 days; Number of cycles: 6; Treatment dose: 175 mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Anastrozole; Initial disease status: Recurrent Disease; Days to treatment start: 246 days; Days to treatment end: 283 days; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Pegylated Liposomal Doxorubicin Hydrochloride; Initial disease status: Recurrent Disease; Days to treatment start: 314 days; Days to treatment end: 417 days (1.1 years); Number of cycles: 6; Treatment dose: 40 mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Topotecan; Initial disease status: Recurrent Disease; Days to treatment start: 424 days (1.2 years); Days to treatment end: 521 days (1.4 years); Number of cycles: 1; Treatment dose: 3 mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Initial disease status: Recurrent Disease; Days to treatment start: 555 days (1.5 years); Days to treatment end: 700 days (1.9 years); Number of cycles: 5; Treatment dose: 343 mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Initial disease status: Recurrent Disease; Days to treatment start: 555 days (1.5 years); Days to treatment end: 700 days (1.9 years); Number of cycles: 5; Treatment dose: 278 mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Initial disease status: Recurrent Disease; Days to treatment start: 555 days (1.5 years); Days to treatment end: 700 days (1.9 years); Number of cycles: 5; Treatment dose: 175 mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 777 days (2.1 years); Treatment anatomic sites: Distant Site.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Docetaxel; Initial disease status: Recurrent Disease; Days to treatment start: 906 days (2.5 years); Days to treatment end: 955 days (2.6 years); Number of cycles: 7; Treatment dose: 30 mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine; Initial disease status: Recurrent Disease; Days to treatment start: 906 days (2.5 years); Days to treatment end: 955 days (2.6 years); Number of cycles: 7; Treatment dose: 700 mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Etoposide; Initial disease status: Recurrent Disease; Days to treatment start: 973 days (2.7 years); Days to treatment end: 990 days (2.7 years); Number of cycles: 1; Treatment dose: 50 mg; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Initial disease status: Recurrent Disease; Days to treatment start: 1,002 days (2.7 years); Days to treatment end: 1,075 days (2.9 years); Number of cycles: 2; Treatment dose: 343 mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Initial disease status: Recurrent Disease; Days to treatment start: 1,002 days (2.7 years); Days to treatment end: 1,081 days (3.0 years); Number of cycles: 2; Treatment dose: 135 mg/m2; Route of administration: Intravenous.
2. Recurrence of diagnosis 1 (Serous cystadenocarcinoma, NOS). Age at diagnosis: 69.2 years (25,273 days); Days to diagnosis: 241 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Recurrent Disease.

Follow-up (2 entries)
- Day 241 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 241 days; Evidence of recurrence type: Convincing Image Source.
- Days to follow up: 1,158 days (3.2 years); Disease response: With Tumor.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-30-1714-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 0.6; Intermediate dimension: 0.4; Shortest dimension: 0.3.
  Slide TCGA-30-1714-01A-02-BS2: Section location: Bottom; Percent tumor cells: 75; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 2; Percent stromal cells: 23.
  Slide TCGA-30-1714-01A-01-BS1: Section location: Top; Percent tumor cells: 60; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 2; Percent stromal cells: 38.
- Sample TCGA-30-1714-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Serous Cystadenocarcinoma; Tumor status: With tumor; History neoadjuvant treatment: No; Jewish religion heritage indicator: Ashkenazi; Method initial path diagnosis: Tumor resection; Lymphovascular invasion indicator: Yes.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 2: Pharmaceutical therapy drug name: Taxol.
- Drug treatment 4: Pharmaceutical therapy drug name: Taxotere.
- Drug treatment 6: Pharmaceutical therapy drug name: VP 16.
- Drug treatment 6, Route of administrations: Route of administration: PO.
- Drug treatment 10: Pharmaceutical therapy drug name: Doxil.
- Drug treatment 13: Pharmaceutical therapy drug name: Armidex.
- Follow-up form: Treatment outcome first course: Complete Remission/Response; Tumor status: With tumor.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,158 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,158 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 241 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-30-1714-01A-02D-0559-01): tumor purity 0.9, ploidy 3.18, whole-genome doublings 1.
